TARGET case TARGET-40-NAAHDN — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cce2bf7b-6361-5b6e-b50e-f8a3116b4856

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 6.3 years (2,318 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,263 days (3.5 years).
   Treatment given: Protocol identifier: BCM.

Follow-up (1 entry)
- Days to follow up: 1,263 days (3.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,263; Year of follow up: 2016.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHDN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-40-NAAHDN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 1263
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Definitive Surgery: Limb sparing
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Percent necrosis at Definitive Surgery: >90
